Somatic mutation profile of tumor specimen TCGA-XF-A8HI-01A (aliquot TCGA-XF-A8HI-01A-11D-A38G-08) from TCGA case TCGA-XF-A8HI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 57.7 years (21,059 days).
Specimen TCGA-XF-A8HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 295e3cf2-9481-4793-8346-2197b92b3ba2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HI-10A (Blood Derived Normal), aliquot TCGA-XF-A8HI-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/495e1818-8bc5-4b97-98e4-b7e1c901e890

The open-access MAF lists 87 somatic variants for this specimen: 59 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 48, Silent 28, Nonsense Mutation 7, Frame Shift Ins 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1709C>T p.A570V (on ENST00000404938 / NM_001163941.2; = p.A125V on NM_178559.6) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.249); catalogued as rs150650141; called by muse, mutect2, varscan2
- ANK2 | c.9445G>C p.E3149Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.329); catalogued as COSV52160742; called by muse, mutect2, varscan2
- ATM | c.8665G>C p.D2889H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781814, COSV53743730, COSV53746235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCOCO1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs746578007, COSV50414049; called by muse, mutect2, varscan2
- CAPN6 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 166/342 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV60694953; called by muse, mutect2, varscan2
- CCDC88A | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV55061485; called by muse, mutect2, varscan2
- CCND1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as rs749614691, COSV57119088; called by muse, mutect2, varscan2
- CD40LG | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1556136676, CM950219, COSV65698474; ClinVar: uncertain significance; called by muse, mutect2
- CDC42BPA | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100505627, COSV62010781; called by muse, mutect2, varscan2
- CELF1 | c.1199G>A p.G400E (on ENST00000358597 / NM_001376422.1; = p.G396E on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60112000; called by muse, mutect2, varscan2
- CELF4 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58452987; called by muse, mutect2, varscan2
- CNKSR3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs564517517, COSV70481062; called by muse, mutect2, varscan2
- CNTF | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV60158857; called by muse, mutect2, varscan2
- COL6A3 | c.5638G>C p.G1880R | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV55089119; called by muse, mutect2, varscan2
- CYBA | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs1260396493, COSV99879908; called by muse, mutect2, varscan2
- DAPK1 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV63787324; called by muse, mutect2, varscan2
- DLGAP5 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1398128763, COSV55963253; called by muse, mutect2, varscan2
- DNAH6 | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV52860536; called by muse, mutect2
- DOP1B | c.4058T>A p.I1353N | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV67693349; called by muse, mutect2, varscan2
- ENPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100093424; called by muse, mutect2, varscan2
- FAM193A | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1163636253, COSV61193974; called by muse, mutect2, varscan2
- FAXC | c.979A>T p.R327W | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67602177; called by muse, mutect2
- GLI2 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.332); catalogued as COSV100083237; called by muse, mutect2
- GPR173 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60234798; called by muse, mutect2, varscan2
- GPR85 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs770350845, COSV51783491; called by muse, mutect2, varscan2
- IRX2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV57410466, COSV57410926; called by muse, mutect2, varscan2
- IST1 | c.850C>T p.H284Y (on ENST00000535424 / NM_001270976.1; = p.H271Y on NM_014761.4) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61709625; called by muse, mutect2, varscan2
- JAK1 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs773295685, COSV61089829; called by muse, mutect2, varscan2
- KDM6A | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV65037736; called by muse, mutect2, varscan2
- KMT2A | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV63281692; called by muse, mutect2, varscan2
- LAS1L | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1296030130, COSV56707299; called by muse, mutect2, varscan2
- LMBRD2 | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56949933; called by muse, mutect2, varscan2
- LRP1B | c.5388C>G p.N1796K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as COSV101257266; called by muse, mutect2
- MAOB | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100956058; called by muse, mutect2, varscan2
- MAP1B | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV57098807; called by muse, mutect2, varscan2
- NDNF | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65633441; called by muse, mutect2, varscan2
- NOD2 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs763955590, COSV56050700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDCD11 | c.2766G>A p.L922= | Splice Region (SNP) | VAF 36/77 reads (47%) | catalogued as rs770553508, COSV63933832; called by muse, mutect2, varscan2
- PIK3CB | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 122/256 reads (48%) | catalogued as COSV100005679; called by muse, mutect2, varscan2
- RAI14 | c.2474G>A p.R825K | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs749355308, COSV54294385; called by muse, mutect2, varscan2
- RUNDC1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV64511834; called by muse, mutect2, varscan2
- SETX | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141974509; called by muse, mutect2, varscan2
- SHROOM3 | c.2637G>C p.Q879H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV56028989; called by muse, mutect2, varscan2
- SLFN11 | c.853C>G p.H285D | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57698815; called by muse, mutect2, varscan2
- SNX12 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as COSV52145632; called by muse, mutect2, varscan2
- SPOP | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV61653357, COSV61653952; called by muse, mutect2, varscan2
- STAG1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); catalogued as COSV52609361; called by muse, mutect2
- SULT2A1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs1032191564, COSV55764962; called by muse, mutect2, varscan2
- SVEP1 | c.3625C>T p.Q1209* | Nonsense Mutation (SNP) | VAF 23/27 reads (85%) | catalogued as COSV100238039; called by muse, mutect2, varscan2
- TCHH | c.5605G>C p.E1869Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.076); catalogued as COSV64274747; called by muse, mutect2, varscan2
- TTN | c.32491G>A p.E10831K (on ENST00000591111; = p.E9904K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | PolyPhen benign (0.269); catalogued as COSV60055274; called by muse, mutect2, varscan2
- TVP23B | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100314531; called by muse, mutect2, varscan2
- UBN2 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56030369; called by muse, mutect2, varscan2
- ZFYVE16 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs1252489508, COSV100566398; called by muse, mutect2, varscan2
- BAP1 | c.682_687del p.F228_N229del | In Frame Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- STAG2 | c.1876dup p.T626Nfs*9 | Frame Shift Ins (INS) | VAF 43/131 reads (33%) | called by mutect2, pindel, varscan2
- TUBB6 | c.691_692insACCG p.A231Dfs*20 | Frame Shift Ins (INS) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- ABCB11 | c.3042C>T p.F1014= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as COSV55590394; called by muse, mutect2, varscan2
- ARHGEF7 | c.723C>G p.V241= (on ENST00000375741 / NM_001113511.2; = p.V63= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV54543126, COSV54546477; called by muse, mutect2, varscan2
- ASPM | c.2715C>G p.L905= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99660393; called by muse, mutect2
- ATP1B2 | c.198C>T p.V66= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV51515615; called by muse, mutect2, varscan2
- ATP2B3 | c.732G>A p.L244= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV54846914; called by muse, mutect2, varscan2
- CCNB3 | c.906A>G p.P302= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV52073507; called by muse, mutect2, varscan2
- CELSR1 | c.5427C>T p.I1809= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs201170657, COSV53082738; called by muse, mutect2, varscan2
- CINP | c.540G>C p.L180= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53736561; called by muse, mutect2, varscan2
- CORO2B | c.564C>T p.F188= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs561018031, COSV55952953; called by muse, mutect2, varscan2
- DDX24 | c.2532G>A p.P844= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as rs776446972, COSV52573439; called by muse, mutect2, varscan2
- DLGAP5 | c.2262G>C p.L754= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV55963242; called by muse, mutect2, varscan2
- FAT2 | c.7980C>T p.F2660= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV55819568; called by muse, mutect2, varscan2
- KARS1 | c.69G>A p.L23= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs755930494, COSV56692167; called by muse, mutect2, varscan2
- KAT6B | c.1710T>C p.R570= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV54746560; called by muse, mutect2, varscan2
- KLHL21 | c.1290G>A p.L430= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1366533147, COSV66553464; called by muse, mutect2, varscan2
- KLHL36 | c.123C>T p.L41= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV50718964; called by muse, mutect2, varscan2
- KLHL36 | c.510C>T p.F170= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV50718986; called by muse, mutect2, varscan2
- LCT | c.5319C>T p.I1773= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV51549153; called by muse, mutect2, varscan2
- NDP | c.201G>A p.G67= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV65203575; called by muse, mutect2, varscan2
- OR2C3 | c.879G>A p.L293= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV63575030; called by muse, mutect2, varscan2
- PDE4DIP | c.1581C>T p.L527= | Silent (SNP) | VAF 56/244 reads (23%) | catalogued as rs782611853, COSV57691914; called by muse, mutect2, varscan2
- PFKP | c.882G>A p.T294= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs747410279, COSV101127246; called by mutect2, varscan2
- SCPEP1 | c.1116C>T p.L372= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs1292548298, COSV51854251; called by muse, mutect2, varscan2
- SLC6A9 | c.903C>G p.V301= (on ENST00000360584 / NM_201649.4; = p.V247= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/159 reads (6%) | catalogued as COSV62210737; called by muse, mutect2
- TPTE | c.1116G>A p.R372= (on ENST00000618007 / NM_199261.4; = p.R354= on NM_199259.4) | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as rs1325288760; called by muse, mutect2, varscan2
- WWP2 | c.2436C>T p.L812= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs1243093880, COSV100598559; called by muse, mutect2, varscan2
- ZNF445 | c.2334C>T p.L778= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV68538845; called by muse, mutect2, varscan2
- ZSCAN5A | c.219G>A p.L73= | Silent (SNP) | VAF 3/67 reads (4%) | catalogued as COSV54227655; called by muse, mutect2
